Somatic mutation profile of tumor specimen TCGA-E8-A3X7-01A (aliquot TCGA-E8-A3X7-01A-11D-A22Z-08) from TCGA case TCGA-E8-A3X7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.4 years (20,983 days).
Specimen TCGA-E8-A3X7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70a8bc1a-48c3-4ae0-888d-ae92db84c1d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A3X7-10A (Blood Derived Normal), aliquot TCGA-E8-A3X7-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77008958-ed5b-4c26-99e3-56cf22445ac4

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FRMPD2 | c.1465A>G p.S489G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100563771; called by muse, mutect2, varscan2
- HECTD1 | c.3770C>T p.A1257V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101237358; called by muse, mutect2, varscan2
- NIPBL | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1039289227, COSV99240191; called by muse, mutect2, varscan2
- PTPRD | c.5507A>G p.Q1836R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100644510; called by muse, mutect2, varscan2
- SLC44A1 | c.1833C>G p.S611R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100570336; called by muse, varscan2
- TCEAL5 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV101013123; called by muse, mutect2
- NEU2 | c.951C>A p.A317= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as rs1329097539, COSV52094025, COSV99290540; called by muse, mutect2, varscan2
